Surgical pathology report (de-identified scan), TCGA case TCGA-JV-A5VE, project TCGA-SARC (Sarcoma), tissue source site BLN - Baylor, specimen TCGA-JV-A5VE-01A (Primary Tumor).

[page 1 of 3]
Result Name	Results	Units	Reference Range
SURGICAL	SURGICAL PATHOLOGY		

(..)

SURGICAL PATHOLOGY REPORT

Final

Date of Service:

Status: Signed Out

MICROSCOPIC DIAGNOSIS:

UTERINE MASS, BIOPSY:

LEIOMYOSARCOMA, SEE COMMENT

UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES, EXCISION:

LEIOMYOSARCOMA, POORLY DIFFERENTIATED, (GRADE 3), 29.0 CM,

SEE DETAILS IN TEMPLATE BELOW

BILATERAL OVARIES AND FALLOPIAN TUBES - UNINVOLVED BY TUMOR

APPENDIX, EXCISION:

FIBROUS OBLITERATION OF THE LUMEN

NO INVOLVEMENT OF APPENDIX PROPER BY LEIOMYOSARCOMA

(LEIOMYOSARCOMA IS PRESENT IN BLOOD COAGULUM ADHERENT TO
EXTERNAL SURFACE OF APPENDIX)

ADHESION OF ANTERIOR ABDOMINAL WALL PERITONEUM, EXCISION:

NO TUMOR PRESENT

RIGHT AORTIC LYMPH NODES, EXCISION:

NO TUMOR PRESENT (0/2)

TUMOR SUMMARY:

Tumor site - Uterine corpus

Tumor size - 29.0 cm in greatest dimension

Histologic type (WHO classification): Leiomyosarcoma

Mitotic rate: 16/10 hpf

Necrosis: Present (extent approximately 15%)

Differentiation: Poorly differentiated (pleomorphic leiomyosarcoma)

Histologic grade (FNCLCC): Grade 3

Margins: Not assessed (multiple unattached tumor fragments received with specimen)

Lymph-vascular invasion: Present

Pathology stage: (utilizing CAP soft tissue sarcoma scheme):

pT2b (tumor more than 5 cm in greatest dimension, deep tumor)

pN0 (number of lymph nodes examined - 2, number of lymph nodes involved - 0)

pM - not applicable

Ancillary studies:

Immunohistochemistry - tumor cells immunoreactive for desmin, smooth muscle actin,

and Caldesmon. No tumor cell immunoreactivity for pankeratin

COMMENT: Original frozen section shows pleomorphic tumor cells in solid growth pattern with significant frozen section artifact present. Although originally interpreted as high grade adenocarcinoma FIGO grade 3, retrospective review in conjunctive with permanent sections reveals poorly differentiated leiomyosarcoma. This finding and final results phoned to Dr.

*Leiomyosarcoma NOS
8890/3*

Site path Corpus Uteri C54.9

CCCF Uterus, NOS C55.9

7/20 4/4/13

Pathologist

[page 2 of 3]
88309; 88331; 88305 x3; 88304; 88342 x4

CLINICAL HISTORY:

Pelvic mass

SPECIMEN SOURCE:

Uterine mass, frozen section; uterus, cervix, bilateral tubes and ovaries; appendix; adherent of anterior abdominal wall peritoneum; right periaortic node

GROSS DESCRIPTION:

FROZEN SECTION DIAGNOSIS, UTERINE MASS: ADENOCARCINOMA, HIGH GRADE, FAVOR ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 3

Communicated to Dr.

Specimen 1, received fresh for intraoperative consultation in a container labeled with the patient's name, medical record number and "uterine mass" consists of pink-tan extremely friable soft tissue fragment (2.1 x 1.5 x 1.2 cm) with hemorrhage. Representative section was submitted for frozen section (A1FS), and the remainder is submitted in cassettes A2 and A3.

INTRAOPERATIVE CONSULTATION, UTERUS, CERVIX, BILATERAL TUBES AND OVARIES WITH FUNDIC TUMOR: GROSS EXAM - EXTENSIVE TUMOR PRESENT, SHOWN TO SURGEON

Specimen 2, received fresh for intraoperative consultation in a container with the patient's name, medical record number and "uterus, cervix, bilateral tubes and ovaries", consists of total hysterectomy specimen that weighs 1,403 gm with attached unremarkable bilateral ovaries (left 2.2 x 1.0 x 0.6 cm, right 2.0 x 1.0 x 0.5 cm) with attached unremarkable fallopian tubes (left 9.0 cm in length and 0.4 cm in diameter, right 9.1 cm in length and 0.3 cm in diameter with fimbriated end each). The uterus measures 25.0 cm fundus to cervix, 16.0 cm left to right, and 8.1 cm anterior to posterior. The cervix measures 3.0 cm x 2.9 cm and covered by pink-tan unremarkable mucosa and 0.6 cm slit-like os. The endocervical canal measures 2.5 cm in length and 1.0 cm in diameter and covered by pink-tan trabeculated unremarkable mucosa.

There is irregular pink-tan friable mass (29.0 x 10.0 x 5.0) that occupies the whole endometrial cavity and replaces most of myometrium and extending to the serosa creating two serosal defects (approximately 3.0 x 1.0 cm, at the posterior surface). The mass creates vaguely two nodules, one occupied the uterine corpus (9.0 x 7.0 x 5.0 cm) and the other extending through the serosa supra fundus (20.0 x 10.0 x 5.0 cm) with minute intervening normal myometrium. The tumor extends into the lower uterine segment. There is no residual recognizable normal endometrium. The mass has friable tan lobulated mottled cut surfaces with extensive hemorrhage and necrosis. The tumor grossly invades more than half of the myometrial thickness and reach to the serosa in multiple areas. Representative sections were submitted for research studies as requested and photographs were taken. Both ovaries and fallopian tubes are grossly unremarkable and uninvolved by the tumor.

Also received in the same container, multiple irregular fragments of tan-friable soft tissue with hemorrhage measuring 10.0 x 9.5 x 4.0 cm in aggregate.

Ink code: blue - anterior, black - posterior.

Section code: B1, anterior cervix; B2, posterior cervix; B3 and B4, representative sections of the anterior lower uterine segment, perpendicular sections, full-thickness; B5 and B6, representative sections of the posterior lower uterine segment, perpendicular section, full-thickness; B7 to B14, representative sections of the tumor in the uterine corpus, anteriorly sequential section from inferior to superior; B15 to B22, representative sections of the tumor in the posterior uterine corpus sequential sections from inferior to superior; B23 to B34, representative sections of the tumor, supra fundus, anterior, sequential sections from inferior to superior; B35 to B46, representative sections of

[page 3 of 3]
the tumor supra fundus, posteriorly sequential sections from inferior to superior (B35 and B23 sections with serosal defects.) B47, representative section of the right ovary, B48, representative cross sections of the right fallopian tube; B49, representative section of the left ovary.; B50, representative cross sections of the left fallopian tube; B51 to B55, representative section of the separate aggregate of tumor. Specimen 3, received fresh in a container with the patient's name, medical record number and "appendix", consists of a vermiform appendix, which measures 4.0 cm in length and 0.3 cm in diameter with attached mesoappendix (4.0 x 2.2 x 0.6 cm) and attached blood clot measuring 3.0 x 2.0 x 0.5 cm. The serosal surface is pink-tan and unremarkable. The tip is fibrotic. Section code: C1, surgical resection margin, en face, tip bisected; C2, representative cross sections; C3, representative section of the blood clot.

Specimen 4, received fresh in a container with the patient's name, medical record number and "adhesion of anterior abdominal wall peritoneum", consists of an irregular fragment of tan-brown soft tissue, which measures 2.0 x 1.9 x 0.5 cm. Specimen is entirely submitted in cassettes D1 and D2. Specimen 5, received in formalin in a container with the patient's name, medical record number and "right aortic lymph node", consists of aggregates of fibroadipose tissue, which measure 2.0 x 1.0 x 0.5 cm in aggregate. Sectioning through the tissue reveals two possible lymph nodes measuring 1.5 and 0.6 cm in greatest dimensions. The specimen is entirely submitted as labeled, E1, one bisected lymph node; E2, one intact lymph node; E3, remainder of the specimen.

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

1xKERATIN PAN, 1xACTIN SMOOTH MUSCLE, 1xDESMIN, 1xIM-CALDESMON
The immunohistochemistry test was developed and its performance characteristics determined by

Pathology Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. The test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.
Performed at

--Electronically Signed Out by

Source: NCI Genomic Data Commons file 1802b92f-fe70-4b35-bad0-64f544997c5d (TCGA-JV-A5VE.3AB00FA2-E66D-42F3-83E8-53D63DF69447.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).